Surgical pathology report (de-identified scan), TCGA case TCGA-61-2018, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2018-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: DIAPHRAGM, BIOPSY -

FIBROMUSCULAR AND ADIPOSE TISSUE WITH MESOTHELIAL LINING, NEGATIVE FOR TUMOR.

PART 2: RIGHT ADNEXA, RIGHT SALPINGO-OOPHORECTOMY -

- A. POORLY DIFFERENTIATED ADENOCARCINOMA WITH ENDOMETRIOID, SEROUS AND TRANSITIONAL FEATURES, 11.5 CM.
- B. RIGHT FALLOPIAN TUBE WITH PARATUBAL CYSTS, NEGATIVE FOR TUMOR.

PART 3: LEFT ADNEXA, LEFT SALPINGO-OOPHORECTOMY -

- A. MODERATELY DIFFERENTIATED ADENOCARCINOMA WITH SEROUS AND ENDOMETRIOID FEATURES, 5.8 CM.
- C. LEFT FALLOPIAN TUBE, NEGATIVE FOR TUMOR.

PART 4: UTERUS, TOTAL ABDOMINAL HYSTERECTOMY (106 GRAMS) -

- A. FOCAL CERVICAL INTRAEPITHELIAL NEOPLASIA 1 (CIN 1).
- B. ECTOCERVICAL MARGINS NEGATIVE.
- C. INACTIVE ENDOMETRIUM.
- D. LEIOMYOMAS, UP TO 0.8 CM.
- E. FOCAL ADENOMYOSIS.

PART 5: ADDITIONAL VAGINAL MARGIN, EXCISION -

SQUAMOUS MUCOSA WITH ACUTE AND CHRONIC INFLAMMATION AND REACTIVE ATYPIA, NEGATIVE FOR TUMOR.

PART 6: BLADDER FLAP #1, BIOPSY -

FIBROADIPOSE TISSUE AND DETACHED FRAGMENT OF BENIGN SQUAMOUS EPITHELIUM, NEGATIVE FOR TUMOR.

PART 7: BLADDER FLAP #2, BIOPSY -

FIBROADIPOSE TISSUE LINED BY MESOTHELIUM, NEGATIVE FOR TUMOR.

PART 8: CUL-DE-SAC #1, BIOPSY -

FIBROADIPOSE TISSUE WITH ACUTE INFLAMMATION, NEGATIVE FOR TUMOR.

PART 9: CUL-DE-SAC #2, BIOPSY -

FIBROADIPOSE TISSUE WITH REACTIVE MESOTHELIAL LINING, NEGATIVE FOR TUMOR.

PART 10: CUL-DE-SAC #3, BIOPSY -

FIBROMUSCULAR AND ADIPOSE TISSUE WITH ACUTE INFLAMMATION, NEGATIVE FOR TUMOR.

PART 11: LEFT PELVIC SIDEWALL, BIOPSY -

FIBROMUSCULAR AND ADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 12: RIGHT PELVIC SIDEWALL, BIOPSY -

FIBROMUSCULAR TISSUE WITH ACUTE INFLAMMATION, NEGATIVE FOR TUMOR.

PART 13: LEFT PELVIC LYMPH NODES, EXCISION -

THREE BENIGN LYMPH NODES, NEGATIVE FOR TUMOR (0/3).

PART 14: RIGHT PELVIC LYMPH NODES, EXCISION -

FIVE BENIGN LYMPH NODES, NEGATIVE FOR TUMOR (0/5).

PART 15: LEFT COMMON AND PERIAORTIC LYMPH NODES, EXCISION -

TWO BENIGN LYMPH NODES, NEGATIVE FOR TUMOR (0/2).

PART 16: RIGHT COMMON AND PERIAORTIC LYMPH NODES, EXCISION -

FOUR BENIGN LYMPH NODES, NEGATIVE FOR TUMOR (0/4).

PART 17: APPENDIX, APPENDECTOMY -

VERMIFORM APPENDIX, NEGATIVE FOR TUMOR.

PART 18: LEFT PERICOLIC GUTTER, BIOPSY -

FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 19: RIGHT PERICOLIC GUTTER, BIOPSY -

FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 20: OMENTUM, OMENTECTOMY -

FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

Source: NCI Genomic Data Commons file 5b380c3d-f50a-4f5d-a448-ea96fabe927f (TCGA-61-2018.2AEC8ABD-7BDC-4CA3-A404-7DCE57AEA7C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).